Somatic mutation profile of tumor specimen C3L-02389-01 (aliquot CPT0203040011) from CPTAC case C3L-02389, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.7 years (24,371 days).
Specimen C3L-02389-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da58e14f-e791-4577-a228-f752103c2533.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02389-74 (Blood Derived Normal), aliquot CPT0203130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d841ba1-e620-4d53-a7c9-da83f9185d27

The open-access MAF lists 1,017 somatic variants for this specimen: 678 protein-altering or splice-affecting, 197 silent, 142 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 197, Frame Shift Del 136, Intron 71, Frame Shift Ins 29, Nonsense Mutation 24, 3'UTR 24, 5'UTR 16, RNA 16, Splice Site 12, 5'Flank 8, Splice Region 8.

Variants (750 of 1,017; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 221/488 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.431); catalogued as rs1057517719, COSV65424948; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 64/179 reads (36%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 130/316 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 64/175 reads (37%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MPZ | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 32/557 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.294); catalogued as rs121913584, CM930494; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 124/318 reads (39%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.389del p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 145/424 reads (34%) | catalogued as rs121913292, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SOS1 | c.1646C>A p.T549K | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs730881046, CM116040; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TAF1 | c.3887T>C p.I1296T (on ENST00000373790 / NM_138923.4; = p.I1317T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/131 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs864321627, CM151914, COSV52111070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TCF20 | c.364dup p.Q122Pfs*12 | Frame Shift Ins (INS) | VAF 83/208 reads (40%) | catalogued as rs777979354; ClinVar: pathogenic; called by mutect2, varscan2
- AARS2 | c.706del p.Q236Sfs*3 | Frame Shift Del (DEL) | VAF 103/274 reads (38%) | catalogued as rs1253616133; called by mutect2, pindel, varscan2
- ABRA | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs764169695; called by muse, mutect2, varscan2
- AC104452.1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1368099067, COSV55533830, COSV99648560; called by muse, mutect2, varscan2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs756288275; called by mutect2, pindel
- ADAMTS8 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 47/564 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99961787; called by muse, mutect2
- ADAR | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 136/604 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781413531, COSV52720076; called by muse, mutect2, varscan2
- ADCY5 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV59198079; called by muse, mutect2, varscan2
- ADGRL4 | c.1985del p.L662Yfs*28 | Frame Shift Del (DEL) | VAF 54/140 reads (39%) | catalogued as rs770040543; called by mutect2, pindel, varscan2
- ADSS1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs775866496; called by muse, mutect2, varscan2
- AJM1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1317335613, COSV56032723; called by muse, mutect2, varscan2
- AKAP10 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99855629; called by muse, mutect2, varscan2
- AL592490.1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780522239, COSV69427358; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALKBH7 | c.656del p.P219Qfs*23 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs767513504; called by mutect2, pindel
- ALS2 | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs768669586; called by muse, mutect2
- ANKRD30A | c.1459C>A p.L487I (on ENST00000611781; = p.L431I on NM_052997.2) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.341); catalogued as COSV64624147; called by muse, mutect2, varscan2
- APBA2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 93/451 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.107); catalogued as rs1337951871; called by muse, mutect2, varscan2
- APOL3 | c.812G>A p.R271H (on ENST00000349314 / NM_145640.2; = p.R200H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200732493; called by muse, mutect2, varscan2
- ARHGEF11 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs201112397; called by muse, mutect2, varscan2
- ARHGEF15 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1480801589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF5 | c.2580del p.R861Gfs*10 | Frame Shift Del (DEL) | VAF 29/190 reads (15%) | catalogued as rs1461198924, COSV50208217; called by mutect2, varscan2
- ARID1A | c.5839C>T p.Q1947* | Nonsense Mutation (SNP) | VAF 92/214 reads (43%) | catalogued as COSV61380856; called by muse, mutect2, varscan2
- ARMC1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs1422990762; called by muse, mutect2, varscan2
- ASXL2 | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV55455149; called by muse, mutect2
- ATP10A | c.3764G>A p.C1255Y | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1306035318; called by muse, mutect2
- ATP10A | c.3035G>A p.S1012N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100791515; called by muse, mutect2
- ATP2A1 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 240/576 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140944847; called by muse, mutect2, varscan2
- ATXN2L | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs747076514; called by muse, mutect2, varscan2
- BAAT | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 148/372 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as rs1363329930; called by muse, mutect2, varscan2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 43/146 reads (29%) | catalogued as rs1555653824; called by mutect2, pindel, varscan2
- BBOX1 | c.218dup p.V74Gfs*8 | Frame Shift Ins (INS) | VAF 16/143 reads (11%) | catalogued as rs1157195022; called by mutect2, pindel, varscan2
- BICDL1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs201940570, COSV99985827; called by muse, mutect2, varscan2
- BIRC6 | c.3680T>C p.V1227A | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV70196983; called by muse, mutect2, varscan2
- BPIFB4 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100971391; called by muse, mutect2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.7688G>A p.R2563Q | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs377277426, COSV99606844; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 94/243 reads (39%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C14orf93 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs145175744; called by muse, mutect2, varscan2
- C1QA | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 166/375 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749595647, COSV101009495; called by muse, mutect2, varscan2
- C1orf226 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 46/219 reads (21%) | catalogued as COSV63396785; called by muse, mutect2, varscan2
- C2CD4D | c.893del p.P298Rfs*8 | Frame Shift Del (DEL) | VAF 108/522 reads (21%) | catalogued as COSV100787629; called by pindel, varscan2
- C9orf131 | c.1929G>T p.R643S | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs116919703; called by muse, mutect2, varscan2
- CACHD1 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 182/475 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs1267570165; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACUL1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs764372626, COSV60995312; called by muse, mutect2, varscan2
- CALR3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 209/496 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1212903941; called by muse, mutect2, varscan2
- CATSPERG | c.3021-1G>T p.X1007_splice | Splice Site (SNP) | VAF 76/185 reads (41%) | catalogued as COSV53054732; called by muse, mutect2, varscan2
- CCDC168 | c.12092del p.K4031Rfs*3 | Frame Shift Del (DEL) | VAF 49/156 reads (31%) | catalogued as rs935958518; called by mutect2, pindel, varscan2
- CCDC33 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs781008556; called by muse, mutect2, varscan2
- CD177 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490894252; called by muse, mutect2
- CDC42BPB | c.4663C>T p.R1555W | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100775648; called by muse, mutect2, varscan2
- CEND1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.087); catalogued as rs1037131256; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs747064410; called by mutect2, varscan2
- CFAP65 | c.361G>A p.A121T (on ENST00000341552 / NM_194302.4; = p.A56T on NM_152389.4) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs752571190, COSV55389204; called by muse, mutect2, varscan2
- CFAP92 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs542814388; called by muse, mutect2
- CGA | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV63644248; called by muse, mutect2, varscan2
- CHAT | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 246/533 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115964813, COSV100339999; called by muse, mutect2, varscan2
- CHERP | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99550059; called by muse, mutect2, varscan2
- CHRNG | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 157/390 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs377704298; called by muse, mutect2, varscan2
- CHST5 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745564989; called by muse, mutect2, varscan2
- CHTOP | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1409145280; called by muse, mutect2, varscan2
- CIZ1 | c.2590G>A p.G864S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as rs555112968; called by muse, mutect2, varscan2
- CLDN23 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs571805093, COSV67731628; called by muse, mutect2, varscan2
- CNTLN | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs765685721, COSV52076884; called by muse, mutect2, varscan2
- COL9A2 | c.104del p.P35Rfs*51 | Frame Shift Del (DEL) | VAF 61/173 reads (35%) | catalogued as rs761125486; called by mutect2, pindel, varscan2
- CRACD | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.033); catalogued as rs1464845933; called by muse, mutect2, varscan2
- CTLA4 | c.529del p.Y177Ifs*10 | Frame Shift Del (DEL) | VAF 97/299 reads (32%) | catalogued as COSV55593336; called by mutect2, pindel, varscan2
- CTNNAL1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 160/401 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs747944532, COSV57702470, COSV57705583; called by muse, mutect2, varscan2
- CWC25 | c.541_543del p.E181del | In Frame Del (DEL) | VAF 41/108 reads (38%) | catalogued as rs765841595; called by mutect2, pindel, varscan2
- CYP4F22 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs140968002; called by muse, mutect2, varscan2
- DCLK1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 81/175 reads (46%) | catalogued as COSV55170784; called by muse, mutect2, varscan2
- DERA | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770297786; called by muse, mutect2, varscan2
- DIO3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV100832173, COSV63773017; called by muse, mutect2, varscan2
- DLK1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs750758776; called by muse, mutect2, varscan2
- DNAH1 | c.10396G>A p.V3466M | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs542699983, COSV70226988, COSV70238632; called by muse, mutect2, varscan2
- DOCK11 | c.4916C>T p.A1639V | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs370101788, COSV52234125; called by muse, mutect2, varscan2
- DRG2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56729714; called by muse, mutect2
- DUS1L | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs76779621, COSV100152400; called by muse, mutect2, varscan2
- EDC4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1214063850; called by muse, mutect2
- EFCAB5 | c.3472C>T p.R1158W | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775384672, COSV100300270; called by muse, mutect2, varscan2
- EHBP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764167148, COSV57079108; called by muse, mutect2, varscan2
- EHD2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 222/516 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV54408047; called by muse, mutect2, varscan2
- ELMO1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 46/152 reads (30%) | catalogued as COSV60306554, COSV60329494; called by muse, mutect2, varscan2
- ELN | c.1969G>A p.A657T (on ENST00000320399 / NM_001278939.1; = p.A624T on NM_000501.4) | Missense Mutation (SNP) | VAF 26/654 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs782693956; called by muse, mutect2
- EPB41L1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs993735906, COSV52435435; called by muse, mutect2
- EPN3 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1408057682; called by muse, mutect2, varscan2
- EYS | c.7484C>A p.S2495Y | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV65480648; called by muse, mutect2
- EZH2 | c.455del p.N152Ifs*15 | Frame Shift Del (DEL) | VAF 90/245 reads (37%) | catalogued as COSV100235433; called by mutect2, pindel, varscan2
- FA2H | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 15/524 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54726996; called by muse, mutect2
- FAM126B | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs372270432; called by muse, mutect2, varscan2
- FAM184B | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as rs752089537, COSV53957498; called by muse, mutect2, varscan2
- FAM91A1 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232302646, COSV58238418; called by muse, mutect2, varscan2
- FAN1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 51/115 reads (44%) | catalogued as COSV62949836, COSV62949934; called by muse, mutect2, varscan2
- FAT4 | c.13201C>T p.R4401C | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773916430; called by muse, mutect2, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs1566257864; called by mutect2, pindel, varscan2
- FCAMR | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 79/449 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs761038004, COSV100249783; called by muse, mutect2, varscan2
- FGD6 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59691290; called by muse, mutect2, varscan2
- FGF6 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs759669908, COSV57403617; called by muse, mutect2, varscan2
- FGFBP2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs146871123; called by muse, mutect2, varscan2
- FLG | c.6517T>C p.S2173P | Missense Mutation (SNP) | VAF 194/1150 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs759398733; called by muse, varscan2
- FLG | c.6497C>A p.S2166Y | Missense Mutation (SNP) | VAF 192/1157 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.867); catalogued as rs1272143669; called by muse, varscan2
- FLG | c.2950C>T p.H984Y | Missense Mutation (SNP) | VAF 260/1167 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs745712294, COSV64246984; called by muse, varscan2
- FLNB | c.7720G>A p.V2574I | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.106); catalogued as rs765974957, COSV55887180; called by muse, mutect2, varscan2
- FNBP1L | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs779110197, COSV53091478; called by muse, mutect2, varscan2
- FOCAD | c.3803C>T p.T1268I | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs775202879; called by muse, mutect2, varscan2
- FSIP2 | c.1139del p.N380Tfs*16 | Frame Shift Del (DEL) | VAF 42/91 reads (46%) | catalogued as rs1559014390; called by mutect2, varscan2
- FUBP3 | c.191-2A>G p.X64_splice | Splice Site (SNP) | VAF 25/211 reads (12%) | catalogued as rs200792962; called by muse, mutect2, varscan2
- GFRA3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs768356926; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 46/129 reads (36%) | catalogued as rs749150409; called by mutect2, varscan2
- GMIP | c.2773dup p.L925Pfs*11 | Frame Shift Ins (INS) | VAF 57/152 reads (38%) | catalogued as rs1192810142; called by mutect2, pindel, varscan2
- GPR6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 163/399 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51572250; called by muse, mutect2, varscan2
- GRIFIN | c.241del p.E81Sfs*5 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs1277608326, COSV101321744; called by mutect2, pindel, varscan2
- GRM7 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 113/264 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV63148833; called by muse, mutect2, varscan2
- H3-4 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 103/641 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs746429747; called by muse, mutect2, varscan2
- H3C6 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 104/294 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1377712944; called by muse, mutect2, varscan2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs1218980629; called by mutect2, varscan2
- HNRNPM | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 245/570 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs778066842, COSV55314213; called by muse, mutect2, varscan2
- HOOK2 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); catalogued as rs759600622; called by muse, mutect2, varscan2
- HPSE2 | c.57del p.A20Rfs*3 | Frame Shift Del (DEL) | VAF 121/346 reads (35%) | catalogued as COSV65189625; called by mutect2, pindel, varscan2
- HSPA1L | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 172/401 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs767230108; called by muse, mutect2, varscan2
- HTATSF1 | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); catalogued as rs748112002, COSV54478687; called by muse, mutect2, varscan2
- IGFN1 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 362/500 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as rs370809446; called by muse, mutect2, varscan2
- IGHV2-70 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 93/120 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs10144844; called by muse, mutect2, varscan2
- IGKV3D-11 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 286/740 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1224364505; called by muse, mutect2
- IGLV4-60 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101135230; called by muse, mutect2, varscan2
- INKA2 | c.559dup p.A187Gfs*3 | Frame Shift Ins (INS) | VAF 65/190 reads (34%) | catalogued as rs751997684; called by mutect2, varscan2
- INPP5B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs200755593; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 54/110 reads (49%) | catalogued as rs760925109; called by mutect2, varscan2
- INTS9 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1207852334, COSV68434610; called by muse, mutect2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 23/178 reads (13%) | catalogued as rs1561359523; called by mutect2, varscan2
- IRF2BP2 | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 76/371 reads (20%) | catalogued as COSV100784325; called by muse, mutect2, varscan2
- ISLR | c.797A>C p.Q266P | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV51434390; called by muse, mutect2, varscan2
- ISYNA1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1453341017; called by muse, mutect2, varscan2
- ITGA10 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 129/559 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs369985596; called by muse, mutect2, varscan2
- ITGA6 | c.3295C>T p.R1099W (on ENST00000442250; = p.R1060W on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs370676535; called by muse, mutect2, varscan2
- KCNA5 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1370940194, CM070953, COSV52908106; called by muse, mutect2, varscan2
- KCNQ1 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 36/726 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs142496309; called by muse, mutect2
- KCNV2 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751709716; called by muse, varscan2
- KCP | c.3015del p.S1006Afs*19 (on ENST00000620378; = p.S1066Afs*19 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 66/191 reads (35%) | catalogued as rs374429628; called by mutect2, pindel, varscan2
- KDF1 | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766818287; called by muse, mutect2, varscan2
- KDM4A | c.1789C>A p.R597S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV64960535; called by muse, mutect2, varscan2
- KEAP1 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99061715; called by muse, mutect2, varscan2
- KIF21A | c.4274T>C p.L1425P (on ENST00000361418 / NM_001378440.1; = p.L1412P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62767707; called by muse, mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 32/102 reads (31%) | catalogued as rs771825279; called by mutect2, pindel, varscan2
- KIFC2 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs749425172, COSV100023846; called by muse, mutect2, varscan2
- KLF4 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1171656170; called by muse, mutect2, varscan2
- KLHL10 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.784); catalogued as COSV53173500; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 38/168 reads (23%) | catalogued as COSV52930337; called by mutect2, varscan2
- KMT2B | c.2307G>A p.M769I | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV52889242; called by muse, mutect2, varscan2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 79/207 reads (38%) | catalogued as rs960845807, COSV54929560; called by mutect2, varscan2
- LAMA2 | c.5291A>G p.E1764G | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs141950826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC2 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 98/521 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1160708758; called by muse, mutect2, varscan2
- LCORL | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778492019, COSV100481628; called by muse, mutect2, varscan2
- LDB3 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV53937418; called by muse, mutect2
- LMX1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as rs202040732, COSV54220618; called by muse, mutect2, varscan2
- LRRC32 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99477145; called by muse, mutect2, varscan2
- MAGEC1 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765302694, COSV99594908; called by muse, mutect2, varscan2
- MAGED2 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 120/161 reads (75%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.731); catalogued as COSV54497937; called by muse, mutect2, varscan2
- MAN2C1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 150/362 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1317761186, COSV99145738; called by muse, mutect2, varscan2
- MAP3K14 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212692615; called by muse, mutect2
- MAPK13 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370006071, COSV52983716; called by muse, mutect2, varscan2
- MAPK14 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs772108703; called by muse, mutect2, varscan2
- MFGE8 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1273675834; called by muse, mutect2, varscan2
- MIS18A | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); catalogued as COSV51590609; called by muse, mutect2
- MMP9 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 175/407 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1465166516; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 78/212 reads (37%) | catalogued as rs755830405; called by mutect2, varscan2
- MON1A | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 159/439 reads (36%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1228618575; called by muse, mutect2, varscan2
- MPP1 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV65728954; called by muse, varscan2
- MTMR11 | c.1919T>C p.L640P (on ENST00000439741 / NM_001145862.2; = p.L568P on NM_181873.3) | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs997452924; called by muse, mutect2, varscan2
- MTMR11 | c.1136G>A p.R379H (on ENST00000439741 / NM_001145862.2; = p.R307H on NM_181873.3) | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989517022, COSV54965603; called by muse, mutect2, varscan2
- MUC12 | c.10010G>A p.S3337N (on ENST00000379442; = p.S3194N on NM_001164462.1) | Missense Mutation (SNP) | VAF 171/3522 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV65183144; called by muse, mutect2
- MUC17 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs200376693; called by muse, mutect2, varscan2
- MYCBP2 | c.11839C>T p.R3947C (on ENST00000357337; = p.R3985C on NM_015057.5) | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1331100566, COSV62020785; called by muse, mutect2, varscan2
- MYH13 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 143/401 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99355319; called by muse, mutect2, varscan2
- MYO1G | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.241); catalogued as rs1461748486; called by muse, mutect2, varscan2
- MYO7A | c.5369G>A p.R1790H | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs372016012; called by muse, mutect2, varscan2
- MYO9A | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772538066, COSV61849412; called by muse, mutect2, varscan2
- NAA50 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs771530207, COSV53786910; called by muse, mutect2, varscan2
- NDUFA7 | c.197del p.P66Lfs*22 | Frame Shift Del (DEL) | VAF 65/197 reads (33%) | catalogued as rs1426048589; called by mutect2, pindel, varscan2
- NID1 | c.2695G>A p.V899M | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748671846, COSV51617969; called by muse, mutect2, varscan2
- NIN | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745827102; called by muse, mutect2, varscan2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 58/157 reads (37%) | catalogued as rs763440516; called by mutect2, varscan2
- NPAS3 | c.1420A>G p.I474V (on ENST00000356141 / NM_001164749.2; = p.I442V on NM_022123.3) | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV60866973; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | catalogued as rs774343392; called by mutect2, varscan2
- NSD1 | c.5458G>A p.V1820M | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752685166, COSV61773772; ClinVar: uncertain significance; called by muse, mutect2
- NT5C1B | c.1802C>T p.A601V (on ENST00000359846 / NM_001199086.2; = p.A541V on NM_033253.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100409903, COSV58396941; called by muse, mutect2, varscan2
- NTF3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1408813478, COSV58417724; called by muse, mutect2, varscan2
- NTNG2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 221/527 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.591); catalogued as rs984477479; called by muse, mutect2, varscan2
- NUCB2 | c.975del p.E326Nfs*11 | Frame Shift Del (DEL) | VAF 55/116 reads (47%) | catalogued as COSV60375677; called by mutect2, varscan2
- OBSCN | c.6589C>T p.R2197C | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs868640041, COSV99472215; called by muse, mutect2, varscan2
- OCA2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 144/390 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1199627951, COSV62352324; called by muse, mutect2, varscan2
- OR14A16 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV62927001; called by muse, mutect2, varscan2
- OR1C1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV68715320; called by muse, mutect2, varscan2
- OR8J3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs775501990, COSV56882258; called by muse, mutect2, varscan2
- OR9Q2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs762084232; called by muse, mutect2, varscan2
- OTOGL | c.6614C>T p.A2205V (on ENST00000547103; = p.A2196V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs574033095, COSV54013021; called by muse, mutect2, varscan2
- PABPC1L | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1200537611; called by muse, mutect2, varscan2
- PATE1 | c.314G>T p.R105M | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs202055498; called by muse, mutect2, varscan2
- PAX2 | c.1091-1G>T p.X364_splice (on ENST00000428433 / NM_003987.5; = p.X341_splice on NM_000278.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 24/312 reads (8%) | catalogued as COSV100695117, COSV62292526; called by muse, mutect2
- PCDHB10 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs782755634; called by muse, mutect2, varscan2
- PCDHGB1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 210/523 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV53960637; called by muse, mutect2, varscan2
- PCP4L1 | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs549268381; called by mutect2, varscan2
- PDZD8 | c.2915C>A p.P972H | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53690487; called by muse, mutect2, varscan2
- PHF24 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs776629054, COSV54274380; called by muse, mutect2, varscan2
- PHF6 | c.374+1G>A p.X125_splice | Splice Site (SNP) | VAF 61/86 reads (71%) | catalogued as COSV59701704, COSV59703755; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 36/80 reads (45%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PINX1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs377311809; called by muse, mutect2, varscan2
- PLEKHG4B | c.1315C>T p.R439* (on ENST00000283426; = p.R795* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 141/323 reads (44%) | catalogued as rs747027011, COSV52052714; called by muse, mutect2, varscan2
- PLPPR3 | c.1462G>A p.A488T (on ENST00000520876 / NM_001270366.2; = p.A516T on NM_024888.2) | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1308555907, COSV62461443; called by muse, mutect2, varscan2
- POLR1A | c.1151T>C p.I384T | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1355756358; called by muse, mutect2
- POLR3C | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1373299276; called by muse, mutect2, varscan2
- POM121L2 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs16897529; called by muse, mutect2, varscan2
- PPM1K | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 126/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs146041562; called by muse, mutect2, varscan2
- PPP1R26 | c.3290del p.G1097Afs*57 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs764146060; called by mutect2, pindel, varscan2
- PPP3CA | c.919del p.S307Qfs*6 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs1295066766; called by mutect2, pindel, varscan2
- PRKACG | c.95del p.G32Efs*27 | Frame Shift Del (DEL) | VAF 75/233 reads (32%) | catalogued as COSV55240575; called by mutect2, pindel, varscan2
- PRKG2 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV52323155; called by muse, mutect2, varscan2
- PRMT7 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 149/308 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs775110866; called by muse, mutect2, varscan2
- PRR14 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); catalogued as COSV54913739; called by muse, mutect2
- PRRC2C | c.6803A>G p.K2268R (on ENST00000367742; = p.K2266R on NM_015172.4) | Missense Mutation (SNP) | VAF 130/598 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs148105554; called by muse, mutect2, varscan2
- PRSS36 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200868172, COSV51635783; called by muse, mutect2, varscan2
- PTCH1 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 168/419 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs758520331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN7 | c.89C>T p.T30M (on ENST00000495688; = p.T69M on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as rs767756746, COSV58314413; called by muse, mutect2, varscan2
- PTPRK | c.2744G>A p.R915Q (on ENST00000368215 / NM_001291984.2; = p.R916Q on NM_002844.4) | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746002316, COSV63898028, COSV63904549; called by muse, mutect2, varscan2
- PYROXD2 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs769939539; called by muse, mutect2, varscan2
- QRICH2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs1470635848; called by muse, mutect2, varscan2
- RAB40AL | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141036852; called by muse, mutect2, varscan2
- RAPGEF1 | c.804del p.K269Sfs*38 | Frame Shift Del (DEL) | VAF 31/187 reads (17%) | catalogued as rs1564570119; called by mutect2, pindel, varscan2
- RARA | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99565541, COSV99565576; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs759247453; called by mutect2, varscan2
- RFC4 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs778552048, COSV56218818; called by muse, mutect2, varscan2
- RGL1 | c.1034del p.K345Rfs*12 (on ENST00000360851 / NM_001297672.2; = p.K380Rfs*12 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/329 reads (12%) | catalogued as rs1290470008; called by mutect2, pindel, varscan2
- RITA1 | c.355T>G p.S119A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1287705537; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 93/236 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS2 | c.45_53del p.G16_G18del | In Frame Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs753857917; called by mutect2, varscan2
- RRAD | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.91); catalogued as rs1296271126; called by muse, mutect2, varscan2
- RRAGA | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs938480600, COSV65842531; called by muse, mutect2, varscan2
- RREB1 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs754168034; called by muse, mutect2, varscan2
- RSPO1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776470656; called by muse, mutect2, varscan2
- RTN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1014346787, COSV50718522; called by muse, mutect2, varscan2
- RTN2 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 106/256 reads (41%) | catalogued as COSV55592970; called by muse, mutect2, varscan2
- RUNX1 | c.1193C>T p.P398L (on ENST00000344691 / NM_001001890.3; = p.P425L on NM_001754.5) | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV55871654, COSV55871942; called by muse, mutect2, varscan2
- SBF1 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 255/611 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs372906814; called by muse, mutect2, varscan2
- SCN4A | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs552714913, COSV101438306; called by muse, mutect2
- SEMA4F | c.556del p.X186_splice | Splice Site (DEL) | VAF 28/84 reads (33%) | catalogued as rs749720924, COSV60283870; called by mutect2, pindel, varscan2
- SERINC5 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs780405380; called by muse, mutect2, varscan2
- SIN3A | c.2955_2956del p.E985Dfs*29 | Frame Shift Del (DEL) | VAF 55/216 reads (25%) | catalogued as rs886037847; called by pindel, varscan2
- SLC15A5 | c.1661_1663del p.L554del | In Frame Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs762922501; called by pindel, varscan2
- SLC44A2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100213191; called by muse, mutect2, varscan2
- SLFN5 | c.2657T>G p.I886S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100249542; called by muse, mutect2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SMYD4 | c.1815G>T p.E605D | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100563182; called by muse, mutect2
- SNX21 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.247); catalogued as COSV54170379; called by muse, varscan2
- SORCS2 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs746929244, COSV61167324; called by muse, mutect2, varscan2
- SPAG17 | c.5716C>T p.R1906C | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs888556091, COSV60462109; called by muse, mutect2, varscan2
- SPAG17 | c.4952G>A p.G1651E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60466598; called by muse, mutect2, varscan2
- SPEG | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs1415924056; called by muse, mutect2, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 62/167 reads (37%) | catalogued as rs771765677; called by mutect2, varscan2
- SPTB | c.4120C>T p.H1374Y | Missense Mutation (SNP) | VAF 51/506 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1221558226; called by muse, mutect2, varscan2
- STIL | c.1643A>G p.N548S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs1224830713; called by muse, mutect2, varscan2
- SUPT6H | c.1671C>G p.H557Q | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100112832; called by muse, mutect2, varscan2
- SV2C | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs1321959078; called by muse, mutect2, varscan2
- SYNE1 | c.16709A>G p.Q5570R (on ENST00000367255 / NM_182961.4; = p.Q5499R on NM_033071.3) | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs928178334, COSV99581007; called by muse, mutect2, varscan2
- TACR3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 200/489 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs747312740, COSV100510872; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCF25 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs756671068, COSV54529015; called by muse, mutect2, varscan2
- TENT4B | c.340_342dup p.N114dup (on ENST00000561678 / NM_001365323.2; = p.N99dup on NM_001040284.3 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 74/202 reads (37%) | catalogued as rs755709682; called by mutect2, varscan2
- TESK1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs767642668; called by muse, mutect2, varscan2
- THSD7A | c.2357C>T p.S786L | Missense Mutation (SNP) | VAF 123/249 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs1405299088, COSV70260673; called by muse, mutect2, varscan2
- TMEM52B | c.253G>A p.E85K (on ENST00000381923 / NM_001079815.1; = p.E65K on NM_153022.4) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765318935, COSV53729758; called by muse, mutect2, varscan2
- TRPM3 | c.3517G>A p.E1173K (on ENST00000357533 / NM_001366142.2; = p.E1028K on NM_020952.6) | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100679075; called by muse, mutect2
- TRPS1 | c.1520del p.K507Rfs*14 (on ENST00000220888 / NM_001330599.2; = p.K520Rfs*14 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 138/339 reads (41%) | catalogued as COSV99629959; called by mutect2, varscan2
- TSPOAP1 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 212/532 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV99273204; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.91714G>A p.D30572N (on ENST00000591111; = p.D23148N on NM_003319.4) | Missense Mutation (SNP) | VAF 130/284 reads (46%) | PolyPhen possibly damaging (0.835); catalogued as rs764561909, COSV60169751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.86419C>T p.R28807C (on ENST00000591111; = p.R21383C on NM_003319.4) | Missense Mutation (SNP) | VAF 105/358 reads (29%) | PolyPhen possibly damaging (0.681); catalogued as rs756030714, COSV59867380, COSV60466098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.78975G>T p.E26325D (on ENST00000591111; = p.E18901D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | PolyPhen benign (0.003); catalogued as COSV60154895; called by muse, mutect2, varscan2
- TULP4 | c.3064dup p.V1022Gfs*80 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | catalogued as rs752011727; called by mutect2, varscan2
- TXLNA | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs1422351338, COSV65313742, COSV65314211; called by muse, mutect2, varscan2
- TYMP | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 47/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374043253; called by muse, mutect2, varscan2
- UMODL1 | c.1727del p.T576Rfs*8 | Frame Shift Del (DEL) | VAF 74/244 reads (30%) | catalogued as COSV61159944; called by pindel, varscan2
- UNC80 | c.2631G>T p.K877N | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV55904458; called by muse, mutect2, varscan2
- UQCRC1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs939548148; called by muse, mutect2
- USP34 | c.8666C>T p.A2889V | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.956); catalogued as rs770849663, COSV68401729; called by muse, mutect2, varscan2
- USP8 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56162897; called by muse, mutect2, varscan2
- VPS45 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as rs782462421; called by muse, mutect2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 69/187 reads (37%) | catalogued as rs752097396; called by mutect2, pindel, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 72/170 reads (42%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK1 | c.6332C>T p.A2111V (on ENST00000315939 / NM_018979.4; = p.A1863V on NM_014823.3) | Missense Mutation (SNP) | VAF 196/496 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1565607049; called by muse, mutect2, varscan2
- WNT10B | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs959383602; called by muse, mutect2, varscan2
- ZDHHC4 | c.344dup p.T116Hfs*16 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | catalogued as rs34551853, COSV60106411; called by mutect2, varscan2
- ZFHX3 | c.314del p.P105Rfs*4 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV51723868; called by pindel, varscan2*
- ZFP42 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100479164; called by muse, mutect2, varscan2
- ZFPM2 | c.2528C>T p.T843M | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); catalogued as rs1448468136, CM147409, COSV65875560; called by muse, mutect2, varscan2
- ZNF131 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs759501809; called by muse, mutect2
- ZNF154 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs772108827; called by muse, mutect2, varscan2
- ZNF267 | c.877A>G p.N293D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1454121837; called by muse, mutect2, varscan2
- ZNF319 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs942638485; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF513 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 99/237 reads (42%) | catalogued as COSV52008053; called by muse, mutect2, varscan2
- ZNF536 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1280378699, COSV62820813; called by muse, mutect2, varscan2
- ZNF592 | c.2671G>A p.V891I | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as rs1009020534; called by muse, mutect2, varscan2
- ZNF618 | c.1873G>A p.A625T (on ENST00000374126 / NM_001318042.2; = p.A532T on NM_133374.2) | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1395596420; called by muse, mutect2, varscan2
- ZNF667 | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1322475377; called by muse, mutect2, varscan2
- ZNF678 | c.1563del p.K521Nfs*30 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | catalogued as rs763710563; called by mutect2, pindel, varscan2
- ZNF79 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs982452595, COSV61070948; called by muse, mutect2, varscan2
- ZNF831 | c.3073del p.D1025Tfs*40 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs775554241, COSV64039592; called by mutect2, varscan2
- AATK | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABCA10 | c.1245del p.F415Lfs*23 | Frame Shift Del (DEL) | VAF 47/136 reads (35%) | called by mutect2, varscan2
- ADAMTS10 | c.2865+8G>A | Splice Region (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- ADCY9 | c.1468G>T p.V490L | Missense Mutation (SNP) | VAF 181/460 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADRA1B | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADRA1D | c.1374del p.G459Efs*86 | Frame Shift Del (DEL) | VAF 61/158 reads (39%) | called by mutect2, pindel, varscan2
- AEBP1 | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 169/368 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- AGAP3 | c.1382dup p.T462Hfs*15 (on ENST00000622464; = p.T498Hfs*15 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 36/159 reads (23%) | called by mutect2, pindel
- AGPS | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- AK9 | c.5278_5279dup p.C1761Ffs*12 | Frame Shift Ins (INS) | VAF 37/96 reads (39%) | called by mutect2, varscan2
- AK9 | c.77del p.L26Cfs*21 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- ALDH6A1 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 149/335 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANAPC4 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- ANGPTL1 | c.91dup p.I31Nfs*13 | Frame Shift Ins (INS) | VAF 42/229 reads (18%) | called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2063dup p.L688Ffs*6 | Frame Shift Ins (INS) | VAF 51/255 reads (20%) | called by mutect2, pindel, varscan2
- ANKK1 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- ANKLE2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ANKS6 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANO6 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- APEX2 | c.1229_1230del p.I410Rfs*4 | Frame Shift Del (DEL) | VAF 90/146 reads (62%) | called by mutect2, pindel, varscan2
- ARG2 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ARHGAP40 | c.41del p.P14Lfs*32 | Frame Shift Del (DEL) | VAF 96/236 reads (41%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ARL10 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ARNT | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARRB2 | c.1063del p.L355Sfs*42 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ASB18 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.195); called by muse, mutect2
- ASF1A | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- ASIC2 | c.1081A>G p.R361G | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ATF7IP | c.330A>T p.E110D | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ATG2A | c.3737del p.P1246Hfs*92 | Frame Shift Del (DEL) | VAF 94/224 reads (42%) | called by mutect2, varscan2
- ATL2 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 120/314 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 193/507 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP9A | c.2342G>A p.C781Y | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATRN | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- AXDND1 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- BAZ1B | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.076); called by muse, mutect2
- BBS9 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- BCAN | c.2531G>A p.C844Y | Missense Mutation (SNP) | VAF 181/884 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCHE | c.626del p.N209Ifs*2 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- BFAR | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BIRC6 | c.10754del p.K3585Sfs*8 | Frame Shift Del (DEL) | VAF 125/343 reads (36%) | called by mutect2, pindel, varscan2
- BMP2K | c.2228A>T p.D743V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- BTBD10 | c.1364T>A p.L455H | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- C11orf95 | c.683del p.G228Afs*33 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- C3 | c.2046A>G p.K682= | Splice Region (SNP) | VAF 129/330 reads (39%) | called by muse, mutect2, varscan2
- C5orf52 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CABCOCO1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1E | c.4349C>T p.A1450V | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CACNA2D4 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CACYBP | c.167A>C p.D56A | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CADM2 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CASP8AP2 | c.5837C>A p.P1946Q | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLN1 | c.582_*3del | Nonstop Mutation (DEL) | VAF 34/107 reads (32%) | called by pindel, varscan2
- CBX8 | c.956del p.G319Afs*37 | Frame Shift Del (DEL) | VAF 58/129 reads (45%) | called by mutect2, varscan2
- CCDC149 | c.1277T>A p.V426D (on ENST00000635206 / NM_001330643.2; = p.V415D on NM_173463.5) | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CCDC166 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CD164L2 | c.519-8C>A | Splice Region (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- CDC42BPA | c.1624_1626del p.Q542del | In Frame Del (DEL) | VAF 28/151 reads (19%) | called by pindel, varscan2
- CDH15 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 155/481 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH17 | c.925del p.Y309Mfs*20 | Frame Shift Del (DEL) | VAF 41/107 reads (38%) | called by mutect2, pindel, varscan2
- CEACAM5 | c.703+5G>T | Splice Region (SNP) | VAF 137/291 reads (47%) | called by muse, mutect2, varscan2
- CELA3A | c.626T>G p.I209S | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CENPF | c.7209del p.E2404Sfs*8 | Frame Shift Del (DEL) | VAF 32/332 reads (10%) | called by mutect2, pindel
- CERS2 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 100/522 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CFAP126 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CFAP99 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CHD3 | c.3728-2A>G p.X1243_splice | Splice Site (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- CHD6 | c.3877G>T p.G1293C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRDL2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CHSY1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 116/281 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL11A2 | c.4103G>T p.R1368M (on ENST00000341947 / NM_080680.3; = p.R1261M on NM_080679.2) | Missense Mutation (SNP) | VAF 238/570 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- CPNE8 | c.575+1G>T p.X192_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- CRACDL | c.1085del p.P362Rfs*137 | Frame Shift Del (DEL) | VAF 34/70 reads (49%) | called by mutect2, varscan2
- CUL7 | c.4926G>T p.Q1642H | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CWH43 | c.357G>A p.R119= | Splice Region (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- CYB561D2 | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DES | c.458A>C p.E153A | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DLC1 | c.3469C>A p.L1157I (on ENST00000276297 / NM_001348081.2; = p.L720I on NM_006094.5) | Missense Mutation (SNP) | VAF 146/378 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMGDH | c.1925A>G p.Q642R | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, mutect2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 64/209 reads (31%) | called by mutect2, pindel, varscan2
- DNAH8 | c.5708T>C p.I1903T | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNAI3 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK10 | c.2608dup p.R870Kfs*18 | Frame Shift Ins (INS) | VAF 62/248 reads (25%) | called by pindel, varscan2
- DPY19L3 | c.1655A>C p.E552A | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTX1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DYRK1A | c.654del p.K218Nfs*4 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- DYRK3 | c.1581del p.R528Dfs*6 | Frame Shift Del (DEL) | VAF 57/257 reads (22%) | called by mutect2, pindel, varscan2
- EEF1G | c.1089del p.F363Lfs*24 | Frame Shift Del (DEL) | VAF 112/329 reads (34%) | called by mutect2, pindel, varscan2
- ELP1 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 125/471 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ENPP7 | c.1069A>G p.N357D | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- EP300 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- ERBIN | c.3682T>G p.F1228V | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ESYT3 | c.1868G>A p.G623D | Missense Mutation (SNP) | VAF 205/477 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVI5L | c.2336G>T p.S779I | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- FAF1 | c.1596_1597dup p.M533Rfs*26 | Frame Shift Ins (INS) | VAF 50/144 reads (35%) | called by mutect2, varscan2
- FAM120C | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- FAM180B | c.140del p.P47Rfs*3 | Frame Shift Del (DEL) | VAF 48/145 reads (33%) | called by mutect2, pindel, varscan2
- FANCD2 | c.3422T>A p.I1141N | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, varscan2
- FASN | c.2431A>G p.N811D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBLL1 | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.45); called by muse, mutect2
- FCGBP | c.1654-1G>T p.X552_splice | Splice Site (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2
- FCRL2 | c.911del p.L304Pfs*21 | Frame Shift Del (DEL) | VAF 116/654 reads (18%) | called by mutect2, pindel, varscan2
- FDX1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FNBP4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOSB | c.776del p.P259Rfs*18 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- FOSL1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FRMPD3 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.8); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- G2E3 | c.1193dup p.N398Kfs*2 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- GBA3 | c.912del p.F304Lfs*10 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | called by mutect2, varscan2
- GOLM2 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GPALPP1 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GPR158 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- GRIN2C | c.798del p.A267Pfs*70 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | called by mutect2, pindel, varscan2
- GRK5 | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GRM1 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2
- GRM6 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 168/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSPT2 | c.322del p.A108Hfs*11 | Frame Shift Del (DEL) | VAF 48/84 reads (57%) | called by mutect2, pindel, varscan2
- GTF3C4 | c.2428C>A p.L810M | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GXYLT1 | c.978dup p.H327Sfs*2 | Frame Shift Ins (INS) | VAF 55/119 reads (46%) | called by mutect2, pindel, varscan2
- H2AC21 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAND1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- HBP1 | c.1411A>G p.R471G | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- HCN3 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- HMX1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDH2 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHV4-28 | c.5A>G p.K2R | Missense Mutation (SNP) | VAF 18/595 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2
- IGSF11 | c.416C>T p.T139I (on ENST00000393775 / NM_001015887.3; = p.T138I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IKBKB | c.696T>A p.H232Q | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IL27 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- INPPL1 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INSRR | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 158/808 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INTS7 | c.2711T>C p.I904T | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- IPPK | c.423T>A p.C141* | Nonsense Mutation (SNP) | VAF 76/190 reads (40%) | called by muse, mutect2, varscan2
- IQSEC3 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA3 | c.1939_1940del p.D647Rfs*50 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by pindel, varscan2
- ITGA4 | c.1843del p.T615Qfs*2 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- ITGA8 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITIH1 | c.2297A>G p.D766G | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPK1 | c.884A>T p.D295V | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPKB | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1L | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KAT8 | c.819T>G p.H273Q | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNH2 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ4 | c.944del p.G315Afs*66 | Frame Shift Del (DEL) | VAF 136/426 reads (32%) | called by mutect2, pindel, varscan2
- KCTD19 | c.2514G>T p.K838N | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIDINS220 | c.2510T>C p.I837T | Missense Mutation (SNP) | VAF 53/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIFC2 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KLF1 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF8 | c.889A>T p.I297F | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- KMT2B | c.7139_7159+2del | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel
- KRBA1 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.508); called by muse, mutect2
- KRTAP2-2 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRTAP27-1 | c.449del p.N150Ifs*62 | Frame Shift Del (DEL) | VAF 55/155 reads (35%) | called by mutect2, pindel, varscan2
- KRTAP5-1 | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 125/419 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LAMA5 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LECT2 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- LGSN | c.1029del p.K343Nfs*7 | Frame Shift Del (DEL) | VAF 44/127 reads (35%) | called by mutect2, pindel, varscan2
- LHB | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 237/546 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LHX2 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- LIFR | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- LINS1 | c.660_661insT p.D221* | Frame Shift Ins (INS) | VAF 40/101 reads (40%) | called by mutect2, pindel*, varscan2
- LINS1 | c.322del p.T108Pfs*12 | Frame Shift Del (DEL) | VAF 97/284 reads (34%) | called by mutect2, pindel, varscan2
- LLGL1 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- LMNTD2 | c.35-5C>T | Splice Region (SNP) | VAF 92/197 reads (47%) | called by muse, mutect2, varscan2
- LRFN4 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRFN4 | c.1842del p.L615Cfs*9 | Frame Shift Del (DEL) | VAF 87/239 reads (36%) | called by mutect2, pindel, varscan2
- LRIG2 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRIT1 | c.1153del p.Q385Rfs*21 | Frame Shift Del (DEL) | VAF 31/168 reads (18%) | called by mutect2, pindel, varscan2
- LRR1 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- LRRC37A2 | c.5093C>T p.A1698V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by mutect2, varscan2
- LRRC49 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LTB4R2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 137/348 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MACC1 | c.1315del p.S439Pfs*8 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | called by mutect2, pindel, varscan2
- MACF1 | c.6058dup p.T2020Nfs*3 | Frame Shift Ins (INS) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- MAGED1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 162/221 reads (73%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MAP1B | c.3115del p.M1039Wfs*7 | Frame Shift Del (DEL) | VAF 127/360 reads (35%) | called by mutect2, pindel, varscan2
- MAP3K19 | c.2899G>T p.D967Y | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARS2 | c.1389C>A p.H463Q | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MBP | c.494G>T p.R165M (on ENST00000355994 / NM_001025101.2; = p.R32M on NM_002385.3) | Missense Mutation (SNP) | VAF 143/372 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCM3AP | c.4948C>A p.L1650M | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- MDH2 | c.927_929del p.S310del | In Frame Del (DEL) | VAF 20/134 reads (15%) | called by pindel, varscan2
- MDN1 | c.8512del p.E2838Rfs*20 | Frame Shift Del (DEL) | VAF 126/355 reads (35%) | called by mutect2, pindel, varscan2
- METTL3 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD14B | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MGAM2 | c.4375G>T p.G1459W | Missense Mutation (SNP) | VAF 154/333 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIB2 | c.3056A>G p.Q1019R | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MIDEAS | c.1974del p.I659Sfs*45 | Frame Shift Del (DEL) | VAF 93/241 reads (39%) | called by mutect2, pindel, varscan2
- MIER1 | c.55_63dup p.S19_S21dup | In Frame Ins (INS) | VAF 26/75 reads (35%) | called by mutect2, varscan2
- MKKS | c.1215G>T p.W405C | Missense Mutation (SNP) | VAF 174/383 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MME | c.2240G>A p.C747Y | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMS19 | c.1154C>G p.A385G | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MPHOSPH8 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2
- MPHOSPH9 | c.1913T>C p.I638T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MTREX | c.1320+2T>C p.X440_splice | Splice Site (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- MUC12 | c.2660G>A p.S887N (on ENST00000379442; = p.S744N on NM_001164462.1) | Missense Mutation (SNP) | VAF 114/1176 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- MUC21 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 105/424 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MUC4 | c.13613dup p.N4538Kfs*70 (on ENST00000463781 / NM_018406.7; = p.N302Kfs*70 on NM_004532.6) | Frame Shift Ins (INS) | VAF 76/198 reads (38%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.1799G>A p.C600Y | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAXE | c.303del p.T102Rfs*54 | Frame Shift Del (DEL) | VAF 91/458 reads (20%) | called by mutect2, pindel, varscan2
- NBPF15 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 197/1304 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- NCF2 | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 160/845 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- NCR3LG1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 6/185 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.184); called by muse, mutect2
- NEFH | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 93/231 reads (40%) | called by muse, mutect2, varscan2
- NEMF | c.574+1G>A p.X192_splice | Splice Site (SNP) | VAF 58/147 reads (39%) | called by muse, mutect2, varscan2
- NIBAN2 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NKX1-1 | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRC4 | c.2747del p.N916Tfs*12 | Frame Shift Del (DEL) | VAF 78/245 reads (32%) | called by mutect2, pindel, varscan2
- NLRX1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- NOD2 | c.2233A>G p.S745G | Missense Mutation (SNP) | VAF 176/403 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NOL9 | c.814del p.R272Gfs*6 | Frame Shift Del (DEL) | VAF 68/227 reads (30%) | called by mutect2, pindel, varscan2
- NOS1 | c.439del p.L147Wfs*63 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | called by mutect2, pindel, varscan2
- NOSTRIN | c.978G>A p.M326I (on ENST00000317647 / NM_001039724.4; = p.M248I on NM_052946.3) | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NPTN | c.1154dup p.N385Kfs*6 | Frame Shift Ins (INS) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- NR2E3 | c.106del p.E36Rfs*6 | Frame Shift Del (DEL) | VAF 7/77 reads (9%) | called by mutect2, pindel
- NRL | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 226/506 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.3456G>A p.W1152* | Nonsense Mutation (SNP) | VAF 112/535 reads (21%) | called by muse, mutect2, varscan2
- NSD2 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NSUN7 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.8479G>A p.A2827T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- OBSCN | c.9481G>A p.D3161N | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBSCN | c.13702C>T p.Q4568* | Nonsense Mutation (SNP) | VAF 442/623 reads (71%) | called by muse, mutect2, varscan2
- OLFM1 | c.304C>T p.Q102* (on ENST00000371793 / NM_001282611.2; = p.Q84* on NM_006334.4) | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | called by mutect2, varscan2
- OR1E1 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OR4C5 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4K5 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OXCT2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PANX2 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PATJ | c.5256del p.R1753Afs*7 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | called by mutect2, pindel, varscan2
- PCDHB12 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHB8 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PCLO | c.8504del p.P2835Hfs*12 | Frame Shift Del (DEL) | VAF 72/217 reads (33%) | called by mutect2, pindel, varscan2
- PCP2 | c.169_170del p.S57Rfs*23 | Frame Shift Del (DEL) | VAF 54/184 reads (29%) | called by pindel, varscan2
- PDC | c.639dup p.A214Cfs*10 | Frame Shift Ins (INS) | VAF 89/480 reads (19%) | called by mutect2, pindel, varscan2
- PDCD1 | c.116del p.P39Qfs*6 | Frame Shift Del (DEL) | VAF 96/263 reads (37%) | called by mutect2, pindel
- PDIK1L | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 85/218 reads (39%) | called by muse, mutect2, varscan2
- PDIK1L | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHGDH | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 249/557 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PI4KB | c.1637_1638del p.E546Gfs*22 (on ENST00000368873 / NM_001369623.1; = p.E558Gfs*22 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 57/325 reads (18%) | called by pindel, varscan2
- PIK3C2B | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- PITRM1 | c.2823G>T p.W941C | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCZ1 | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PNMT | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- POLB | c.392A>T p.K131I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- POLD1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- POLR2A | c.1188dup p.F397Lfs*4 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- PPEF1 | c.775del p.R259Efs*36 | Frame Shift Del (DEL) | VAF 47/76 reads (62%) | called by mutect2, pindel, varscan2
- PPP2R5D | c.1659_1660del p.E554Gfs*97 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | called by mutect2, pindel, varscan2
- PRKAR1B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- PRKDC | c.12110del p.N4037Ifs*15 | Frame Shift Del (DEL) | VAF 68/199 reads (34%) | called by mutect2, pindel, varscan2
- PRR19 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- PRRC2C | c.6563C>A p.S2188Y (on ENST00000367742; = p.S2186Y on NM_015172.4) | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRSS21 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PSMD6 | c.515_517del p.G172del | In Frame Del (DEL) | VAF 42/122 reads (34%) | called by pindel, varscan2
- PTPN21 | c.807dup p.A270Cfs*7 | Frame Shift Ins (INS) | VAF 25/281 reads (9%) | called by mutect2, pindel
- PXDNL | c.1363del p.T455Qfs*19 | Frame Shift Del (DEL) | VAF 115/320 reads (36%) | called by mutect2, pindel, varscan2
- RABGGTA | c.1234A>G p.K412E | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI1 | c.3142del p.A1048Pfs*16 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.4991T>G p.F1664C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAPH1 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 120/385 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBBP6 | c.4594del p.S1532Vfs*30 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, varscan2
- REXO1 | c.3490del p.L1164Sfs*46 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | called by mutect2, pindel, varscan2
- RGS17 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, varscan2
- RIN2 | c.1673C>A p.T558N (on ENST00000255006 / NM_001242581.1; = p.T509N on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/418 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RIOK3 | c.306del p.K102Nfs*68 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- RNF112 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- RNF133 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RRAGA | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RRS1 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 121/305 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- SBF1 | c.2744del p.G915Afs*47 | Frame Shift Del (DEL) | VAF 71/183 reads (39%) | called by mutect2, pindel, varscan2
- SCUBE2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SDK2 | c.4209del p.S1404Afs*10 | Frame Shift Del (DEL) | VAF 73/211 reads (35%) | called by mutect2, pindel, varscan2
- SDS | c.559del p.D187Tfs*39 | Frame Shift Del (DEL) | VAF 73/244 reads (30%) | called by mutect2, pindel, varscan2
- SERPINE1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETBP1 | c.440dup p.N147Kfs*2 | Frame Shift Ins (INS) | VAF 130/374 reads (35%) | called by mutect2, pindel, varscan2
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 48/110 reads (44%) | called by mutect2, varscan2
- SHANK3 | c.5036G>A p.R1679H | Missense Mutation (SNP) | VAF 218/540 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SIDT1 | c.1320del p.K440Nfs*20 | Frame Shift Del (DEL) | VAF 70/214 reads (33%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.2324del p.P775Lfs*26 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.607G>A p.V203M (on ENST00000454036 / NM_001134771.2; = p.V180M on NM_020708.5) | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A7 | c.908dup p.D304Gfs*50 | Frame Shift Ins (INS) | VAF 60/184 reads (33%) | called by mutect2, pindel
- SLC16A10 | c.186del p.E63Nfs*11 | Frame Shift Del (DEL) | VAF 77/212 reads (36%) | called by mutect2, pindel, varscan2
- SLC39A2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- SLC44A1 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2
- SLC7A4 | c.1869del p.S624Afs*14 | Frame Shift Del (DEL) | VAF 56/180 reads (31%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 122/329 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SMARCB1 | c.878C>T p.A293V (on ENST00000263121; = p.A339V on NM_003073.5) | Missense Mutation (SNP) | VAF 20/690 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.255); called by muse, mutect2
- SMC1B | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- SNED1 | c.2102del p.P701Rfs*4 | Frame Shift Del (DEL) | VAF 137/391 reads (35%) | called by mutect2, pindel, varscan2
- SOX9 | c.1121del p.P374Rfs*9 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, varscan2
- SP4 | c.1493del p.P498Qfs*23 | Frame Shift Del (DEL) | VAF 100/262 reads (38%) | called by mutect2, pindel, varscan2
- SPAG17 | c.846dup p.L283Ifs*11 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- SPEG | c.2607del p.T870Pfs*11 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- STH | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2
- SYNE1 | c.24065C>T p.A8022V (on ENST00000367255 / NM_182961.4; = p.A7951V on NM_033071.3) | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYNE1 | c.15800C>T p.A5267V (on ENST00000367255 / NM_182961.4; = p.A5196V on NM_033071.3) | Missense Mutation (SNP) | VAF 184/427 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SZT2 | c.9072G>T p.Q3024H (on ENST00000634258 / NM_001365999.1; = p.Q2967H on NM_015284.4) | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAAR2 | c.866A>G p.N289S (on ENST00000367931 / NM_001033080.1; = p.N244S on NM_014626.3) | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAB1 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TAOK1 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TAS2R5 | c.678C>A p.C226* | Nonsense Mutation (SNP) | VAF 59/130 reads (45%) | called by muse, mutect2, varscan2
- TATDN1 | c.351dup p.D118* | Frame Shift Ins (INS) | VAF 51/151 reads (34%) | called by mutect2, pindel, varscan2
- TBC1D30 | c.2213A>G p.N738S (on ENST00000542120; = p.N575S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 55/145 reads (38%) | called by mutect2, pindel, varscan2
- TENT4B | c.1001G>A p.G334D (on ENST00000561678 / NM_001365323.2; = p.G319D on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX15 | c.5122del p.R1708Gfs*3 (on ENST00000256246; = p.R2091Gfs*3 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- TICRR | c.1973T>A p.I658N | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TLE1 | c.356T>A p.L119* | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | called by muse, mutect2, varscan2
- TLE6 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TM2D1 | c.513+1G>A p.X171_splice | Splice Site (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- TMEM222 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2
- TMEM31 | c.35_37del p.Q12del | In Frame Del (DEL) | VAF 74/100 reads (74%) | called by pindel, varscan2
- TNKS2 | c.3229G>T p.G1077* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- TOE1 | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TONSL | c.852_853del p.N285Pfs*18 | Frame Shift Del (DEL) | VAF 89/274 reads (32%) | called by mutect2, pindel, varscan2
- TOP1 | c.278del p.K93Rfs*10 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- TOX4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRIM42 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 72/439 reads (16%) | called by muse, mutect2, varscan2
- TRIM75P | c.951A>C p.R317S | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRPM6 | c.5395C>T p.Q1799* | Nonsense Mutation (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- TSHZ2 | c.2753del p.N918Tfs*28 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- TSR1 | c.959del p.K320Rfs*15 | Frame Shift Del (DEL) | VAF 56/125 reads (45%) | called by mutect2, pindel, varscan2
- TTC3 | c.5819G>A p.G1940E | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UBE3B | c.2628-2A>G p.X876_splice | Splice Site (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- ULK1 | c.2618del p.G873Afs*18 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- UNC80 | c.7394del p.N2465Tfs*33 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel
- USP36 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- USP54 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2
- UTP20 | c.7055C>A p.S2352Y | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- UTP23 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VANGL2 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 306/1380 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VARS1 | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- VPS72 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 34/804 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2
- WDR13 | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- WDR27 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR4 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WEE2 | c.1534del p.R512Gfs*3 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- WWC1 | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- XIRP2 | c.4915C>T p.H1639Y (on ENST00000628543; = p.H1814Y on NM_152381.6) | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- YTHDF1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZAN | c.6698G>A p.G2233D | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZAR1 | c.679dup p.E227Gfs*125 | Frame Shift Ins (INS) | VAF 30/72 reads (42%) | called by mutect2, varscan2
- ZBED3 | c.108_113del p.P37_P38del | In Frame Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/150 reads (41%) | called by mutect2, pindel, varscan2
- ZDHHC8 | c.742del p.L248Wfs*16 | Frame Shift Del (DEL) | VAF 52/120 reads (43%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.1016del p.G339Afs*122 | Frame Shift Del (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.265_272del p.S89Gfs*11 | Frame Shift Del (DEL) | VAF 79/229 reads (34%) | called by mutect2, pindel, varscan2
- ZFP37 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZFP37 | c.1432A>T p.I478L | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZFP64 | c.850del p.E284Rfs*15 | Frame Shift Del (DEL) | VAF 80/255 reads (31%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.2707del p.H903Tfs*9 | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | called by mutect2, pindel, varscan2
- ZMIZ2 | c.2614A>G p.S872G | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF208 | c.1901A>G p.E634G | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZNF263 | c.1769T>C p.L590P | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF462 | c.5797A>G p.S1933G | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ZNF502 | c.-58G>A | Splice Region (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- ZNF529 | c.1508A>G p.E503G | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ZNF579 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZNF91 | c.1663T>G p.F555V | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF92 | c.990del p.K330Nfs*4 (on ENST00000328747 / NM_152626.4; = p.K261Nfs*4 on NM_007139.4) | Frame Shift Del (DEL) | VAF 112/278 reads (40%) | called by mutect2, pindel, varscan2
- AATK | c.543G>A p.K181= (on ENST00000326724 / NM_001080395.3; = p.K78= on NM_004920.2) | Silent (SNP) | VAF 163/387 reads (42%) | catalogued as rs1041989910; called by muse, mutect2, varscan2
- ABCC9 | c.667C>T p.L223= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as rs891853102, COSV53962657, COSV53983715; called by muse, mutect2, varscan2
- ADAM19 | c.2784G>A p.K928= | Silent (SNP) | VAF 35/380 reads (9%) | catalogued as rs910509547; called by muse, mutect2
- ADSS1 | c.921C>T p.I307= | Silent (SNP) | VAF 90/194 reads (46%) | catalogued as rs747632771, COSV58274523; called by muse, mutect2, varscan2
- AGBL3 | c.1551A>G p.T517= | Silent (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- AKAP13 | c.6324A>G p.V2108= (on ENST00000394518 / NM_007200.5; = p.V2112= on NM_006738.6) | Silent (SNP) | VAF 92/220 reads (42%) | catalogued as rs556255660; called by muse, mutect2, varscan2
- AKAP3 | c.210A>G p.E70= | Silent (SNP) | VAF 82/194 reads (42%) | called by muse, mutect2, varscan2
- AKR1A1 | c.894T>C p.Y298= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as rs762553762; called by muse, mutect2, varscan2
- AMIGO2 | c.1131C>T p.D377= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs774547090, COSV99873666; called by muse, mutect2, varscan2
- ANGPTL8 | c.474G>A p.K158= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as rs940570679; called by muse, mutect2
- ANKRD24 | c.2529G>C p.R843= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- ANO9 | c.1656C>T p.T552= | Silent (SNP) | VAF 102/224 reads (46%) | catalogued as rs760436010; called by muse, mutect2, varscan2
- APOBR | c.1698G>A p.K566= (on ENST00000431282; = p.K575= on NM_018690.4) | Silent (SNP) | VAF 69/185 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.2310C>T p.I770= | Silent (SNP) | VAF 13/259 reads (5%) | called by muse, mutect2
- ARHGAP6 | c.1830C>T p.N610= | Silent (SNP) | VAF 80/104 reads (77%) | catalogued as rs202126267, COSV57294117; called by muse, mutect2, varscan2
- ATG14 | c.903C>T p.Y301= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as rs1322786911; called by muse, mutect2, varscan2
- ATG2A | c.207G>A p.P69= | Silent (SNP) | VAF 115/259 reads (44%) | catalogued as rs915162998; called by muse, mutect2, varscan2
- ATP2A3 | c.873C>T p.G291= | Silent (SNP) | VAF 243/643 reads (38%) | catalogued as rs904945216; called by muse, mutect2, varscan2
- BACE2 | c.37C>T p.L13= | Silent (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- BCL11A | c.1320C>T p.N440= (on ENST00000335712 / NM_001365609.1; = p.N474= on NM_018014.4) | Silent (SNP) | VAF 80/209 reads (38%) | catalogued as COSV59624915, COSV59635637; called by muse, mutect2, varscan2
- BNIPL | c.1074G>A p.*358= | Silent (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- BRPF3 | c.3156C>T p.N1052= | Silent (SNP) | VAF 132/311 reads (42%) | catalogued as rs961329004; called by muse, mutect2, varscan2
- BRWD3 | c.2733G>T p.L911= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as rs755672459; called by muse, mutect2, varscan2
- C11orf80 | c.748C>T p.L250= | Silent (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- C2CD4D | c.741G>A p.P247= | Silent (SNP) | VAF 34/121 reads (28%) | called by muse, varscan2
- C9orf50 | c.831C>T p.D277= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs749918326; called by muse, mutect2, varscan2
- CACNA1C | c.4968C>A p.R1656= | Silent (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
- CACNA1H | c.2521C>T p.L841= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- CAPN8 | c.486T>C p.N162= | Silent (SNP) | VAF 37/189 reads (20%) | called by muse, mutect2, varscan2
- CARMIL1 | c.1200C>A p.S400= | Silent (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- CCND3 | c.312G>A p.A104= | Silent (SNP) | VAF 252/666 reads (38%) | called by muse, mutect2, varscan2
- CD22 | c.2379G>A p.T793= | Silent (SNP) | VAF 109/313 reads (35%) | catalogued as rs371559984, COSV50063577; called by muse, mutect2, varscan2
- CDK13 | c.1950G>A p.P650= | Silent (SNP) | VAF 90/205 reads (44%) | catalogued as rs1196171608, COSV51707072; called by muse, mutect2, varscan2
- CDRT1 | c.1386T>C p.C462= | Silent (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- CLIC6 | c.546G>A p.A182= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- CNNM4 | c.1644G>A p.P548= | Silent (SNP) | VAF 233/596 reads (39%) | catalogued as rs764568597, COSV65660507; called by muse, mutect2, varscan2
- CNR1 | c.516C>T p.Y172= | Silent (SNP) | VAF 81/222 reads (36%) | catalogued as rs780413917; called by muse, mutect2, varscan2
- CRYBA4 | c.330C>T p.F110= | Silent (SNP) | VAF 158/385 reads (41%) | catalogued as rs376978067; called by muse, mutect2, varscan2
- CTIF | c.1758G>A p.T586= | Silent (SNP) | VAF 35/390 reads (9%) | catalogued as rs745825021, COSV56485013; called by muse, mutect2
- CTU1 | c.810C>T p.A270= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- DCLRE1A | c.1146T>C p.N382= | Silent (SNP) | VAF 83/181 reads (46%) | called by muse, mutect2, varscan2
- DCTN1 | c.1458G>A p.R486= | Silent (SNP) | VAF 162/363 reads (45%) | called by muse, mutect2, varscan2
- DCTN4 | c.13C>T p.L5= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as rs1215100059, COSV69783113; called by muse, mutect2, varscan2
- DENND3 | c.1621C>T p.L541= | Silent (SNP) | VAF 167/452 reads (37%) | called by muse, mutect2, varscan2
- DKK2 | c.165G>T p.A55= | Silent (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- DLEC1 | c.1248C>T p.F416= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs552051755, COSV100342871; called by muse, mutect2
- DNAJB4 | c.645T>C p.T215= | Silent (SNP) | VAF 55/158 reads (35%) | called by muse, mutect2, varscan2
- DNAJC6 | c.2115G>A p.P705= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs367640667; called by muse, mutect2, varscan2
- DTX1 | c.1110C>A p.P370= | Silent (SNP) | VAF 93/224 reads (42%) | catalogued as COSV99986345; called by muse, mutect2, varscan2
- EGR2 | c.1011G>A p.E337= | Silent (SNP) | VAF 122/319 reads (38%) | called by muse, mutect2, varscan2
- ERFE | c.435G>A p.R145= | Silent (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- EZH1 | c.2211C>T p.Y737= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs1304667407, COSV52850275; called by muse, mutect2, varscan2
- F8A1 | c.1098C>A p.P366= | Silent (SNP) | VAF 116/420 reads (28%) | called by muse, mutect2, varscan2
- FASTKD5 | c.1962C>A p.P654= | Silent (SNP) | VAF 140/358 reads (39%) | called by muse, mutect2, varscan2
- FBXO36 | c.228T>C p.G76= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- FGD3 | c.552C>T p.C184= | Silent (SNP) | VAF 67/153 reads (44%) | called by muse, mutect2, varscan2
- FGD5 | c.615G>A p.E205= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- FGF23 | c.609G>A p.P203= | Silent (SNP) | VAF 68/146 reads (47%) | catalogued as rs1429413031, COSV99426727; called by muse, mutect2, varscan2
- FOXD4L4 | c.228C>T p.G76= | Silent (SNP) | VAF 271/805 reads (34%) | called by muse, mutect2, varscan2
- FUBP1 | c.63C>T p.G21= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as rs1443721865, COSV53932759; called by muse, varscan2
- GABRD | c.858G>A p.T286= | Silent (SNP) | VAF 153/342 reads (45%) | catalogued as rs372178849; called by muse, mutect2, varscan2
- GAL3ST2 | c.132C>T p.G44= | Silent (SNP) | VAF 99/183 reads (54%) | called by muse, mutect2, varscan2
- GALNT18 | c.1458G>T p.G486= | Silent (SNP) | VAF 56/185 reads (30%) | called by muse, mutect2, varscan2
- GATA3 | c.132G>A p.P44= | Silent (SNP) | VAF 252/544 reads (46%) | catalogued as rs769859105; called by muse, mutect2, varscan2
- GDF6 | c.1080C>T p.H360= | Silent (SNP) | VAF 29/788 reads (4%) | catalogued as COSV99748782; called by muse, mutect2
- GIT2 | c.1182C>T p.S394= (on ENST00000355312 / NM_057169.5; = p.S396= on NM_014776.5) | Silent (SNP) | VAF 97/217 reads (45%) | catalogued as rs776840737; called by muse, mutect2, varscan2
- GNAL | c.258C>T p.R86= | Silent (SNP) | VAF 122/292 reads (42%) | called by muse, mutect2, varscan2
- GOLGA6D | c.1626G>A p.A542= | Silent (SNP) | VAF 153/739 reads (21%) | catalogued as rs1260077736; called by muse, mutect2, varscan2
- GREB1 | c.1689C>T p.A563= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs756550068; called by muse, mutect2, varscan2
- GRIN3A | c.153C>A p.G51= | Silent (SNP) | VAF 110/232 reads (47%) | catalogued as rs762343940, COSV62456307; called by muse, mutect2, varscan2
- GRIP1 | c.336C>T p.F112= | Silent (SNP) | VAF 12/301 reads (4%) | catalogued as COSV54039879; called by muse, mutect2
- GRXCR1 | c.510T>C p.F170= | Silent (SNP) | VAF 142/320 reads (44%) | called by muse, mutect2, varscan2
267 further variants in this file (0 protein-altering or splice-affecting, 125 silent, 142 other) are not listed here.
